Gene-level copy-number profile of specimen HCM-SANG-0313-C15-85A-01D-A80T-32 from HCMI case HCM-SANG-0313-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS.
Specimen HCM-SANG-0313-C15-85A-01D-A80T-32: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 68298c70-07a3-4225-9d3c-9c779f8c3e6c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0313-C15-10A-01D-A80T-32 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,724 have no estimate.
https://portal.gdc.cancer.gov/files/e74b5118-06e0-49f4-8a24-6e28682841be

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 36; copy number 1: 1,789; copy number 2: 22,166; copy number 3: 26,530; copy number 4: 5,382; copy number 5: 2,095; copy number 6: 673; copy number 7: 162; copy number 8: 23; copy number 9: 23; copy number 10: 20.

Homozygous deletions (total copy number 0; autosomes only): 36 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:4,303,304–4,847,840, 4 genes (within-gene range 0–2): SETMAR, MRPS10P2, ITPR1-DT, ITPR1.
- chr8:39,451,045–39,522,852, 1 gene: ADAM3A.
- chr16:78,495,926–78,553,296, 4 genes (within-gene range 0–2): AC046158.1, AC046158.4, AC046158.2, AC046158.3.
- chr20:14,933,843–14,935,363, 1 gene (within-gene range 0–3): AL138808.1.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 228 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:24,007,881–24,112,135, 4 genes, copy number 7: AL590609.1, AL591178.1, MYOM3, MYOM3-AS1.
- chr3:185,914,558–185,980,872, 2 genes, copy number 7: TRA2B, NMRAL2P.
- chr6:29,657,002–30,364,280, 67 genes, copy number 7–9 (broad region; genes not listed).
- chr6:42,879,616–43,288,258, 26 genes, copy number 7: RPL7L1, C6orf226, PTCRA, AL035587.2, CNPY3, AL035587.1, RPL24P4, GNMT, PEX6, PPP2R5D, MEA1, KLHDC3, RRP36, AL136304.1, RN7SL403P, CUL7, KLC4, AL355385.2, MRPL2, AL355385.1, PTK7, SRF, CUL9, AL133375.1, DNPH1, TTBK1.
- chr6:43,477,523–44,553,281, 43 genes, copy number 8–10: TJAP1, LRRC73, POLR1C, YIPF3, AL355802.3, XPO5, AL355802.1, AL355802.2, POLH, POLH-AS1, GTPBP2, MAD2L1BP, RSPH9, MRPS18A, AL136131.1, AL136131.2, VEGFA, AL136131.3, LINC02537, AL157371.1, AL109615.3, C6orf223, AL109615.2, AL109615.1, MRPL14, TMEM63B, CAPN11, RN7SL811P, MYMX, SLC29A1, HSP90AB1, SLC35B2, MIR4647, NFKBIE, TMEM151B, AL353588.1, TCTE1, AARS2, SPATS1, CDC5L, MIR4642, AL136140.1, AL136140.2.
- chr9:124,001,670–124,033,301, 1 gene, copy number 7 (within-gene range 3–7): LHX2.
- chr9:124,031,624–124,032,524, 1 gene, copy number 7: AC006450.2.
- chr11:10,308,313–10,541,230, 5 genes, copy number 7: AMPD3, RNU6ATAC33P, MTRNR2L8, MIR4485, RNF141.
- chr14:49,057,713–50,231,578, 40 genes, copy number 7: AL110505.1, ATP5MC2P2, RNA5SP384, RPS29, RPL32P29, RN7SL1, Y_RNA, LRR1, RHOQP1, AL139099.3, RPL36AL, MGAT2, AL139099.1, DNAAF2, AL139099.2, POLE2, STK16P1, AL591767.2, RNU6ATAC30P, KLHDC1, AL591767.1, KLHDC2, NEMF, Y_RNA, RNU6-539P, RN7SL3, AL627171.2, RN7SL2, AL627171.1, ARF6, RNU6-189P, Metazoa_SRP, LINC01588, MIR6076, PDLIM1P1, AL117692.1, RN7SKP193, Y_RNA, VCPKMT, SOS2.
- chr14:50,312,324–50,335,558, 1 gene, copy number 7 (within-gene range 2–7): DMAC2L.
- chr15:21,927,657–21,946,641, 1 gene, copy number 7: NF1P2.
- chr15:79,989,905–80,015,707, 2 genes, copy number 7: AC015871.5, AC092701.1.
- chr17:39,566,915–39,747,291, 12 genes, copy number 10: AC009283.1, NEUROD2, AC087491.1, PPP1R1B, STARD3, TCAP, PNMT, PGAP3, ERBB2, MIR4728, MIEN1, GRB7.
- chr17:58,166,982–58,268,518, 7 genes, copy number 8: OR4D2, EPX, AC005962.1, MKS1, LPO, AC005962.2, AC004687.3.
- chr19:2,252,252–2,341,172, 7 genes, copy number 7 (within-gene range 5–7): JSRP1, OAZ1, AC005258.1, PEAK3, LINGO3, AC104530.1, AC005258.2.
- chr19:45,485,294–45,645,602, 8 genes, copy number 7: RTN2, PPM1N, VASP, OPA3, GPR4, EML2, MIR330, EML2-AS1.
- chr19:48,485,271–48,513,935, 1 gene, copy number 8: LMTK3.

Autosomal genes at a single copy (total copy number 1): 760. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
